Somatic mutation profile of tumor specimen 96c95de1-514b-44a5-b487-dc390b (aliquot 96c95de1-514b-44a5-b487-dc390b_D6) from CPTAC case 03BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.4 years (22,417 days).
Specimen 96c95de1-514b-44a5-b487-dc390b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c8e2db1-8757-4ab0-b22e-9f881a6d3699.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b66903d8-088e-496e-97b7-348a9e (Blood Derived Normal), aliquot b66903d8-088e-496e-97b7-348a9e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5aa67fb8-bc7f-42fc-9441-98d5bcfa9de8

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CERS3 | c.870G>T p.L290F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.255); called by muse, varscan2
- PGM2 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZSCAN21 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.397); called by muse, mutect2
